Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7877, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7877-01A (Primary Tumor).

Microscopic

Sections demonstrate a variably cellular glioma that diffusely infiltrates both the gray and white matter. In the gray matter, perineural satellitosis, perivascular satellitosis and subpial condensation are all seen. The tumor cells consistently have round nuclei with mild to moderate atypia. Most have perinuclear halos. Neither microvascular proliferation nor tumor necrosis are seen. As noted, cellularity is variable, ranging from modest to nearly confluent. In these more cellular areas, scattered mitoses are seen with iup to 4 mitoses per 10 high power fields, although most areas show fewer.

Addendum

Scattered MIB-1 reactive cells are present throughout the tumor. In the most proliferative region, a labeling index of 4.4% is calculated. This is evidence against anaplastic progression. Nevertheless, the mildly elevated mitotic count warrants close follow up.

Diagnosis

Low grade oligodendroglioma grade II

Source: NCI Genomic Data Commons file 3f4c758a-31a1-4a4c-9739-66ed80bcf9c4 (TCGA-HT-7877.C9BDAE23-9523-46E1-8F14-E3C2A94E0200.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).